Surgical pathology report (de-identified scan), TCGA case TCGA-HZ-8637, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HZ-8637-01A (Primary Tumor).

[page 1 of 4]
Diagnosis:

PANCREAS, STOMACH, SMALL BOWEL, WHIPPLE PROCEDURE:

- Invasive adenocarcinoma, moderately to poorly differentiated.
- Tumor size 3.4 cm.
- Tumor extends into peripancreatic soft tissue.
- Tumor invades into ampulla of Vater.
- Surgical margins negative, see comment.
- One of eighteen lymph nodes POSITIVE (1/18).

PATHOLOGIC TUMOR STAGING SYNOPSIS (EXOCRINE PANCREAS):

Type and grade: Invasive adenocarcinoma, moderately to poorly differentiated.

Primary tumor: pT3

Regional lymph nodes: pN1

Distant metastasis: N/A

Pathologic stage: IIB

Lymphovascular invasion: Not identified.

Margin status: R0, negative.

COMMENT: The surgical margins are negative with adenocarcinoma 2 mm from the posterior-inferior margin.

Tumor Staging Information

Data derived from current specimen. Staging in accordance with or modified from AJCC Cancer Staging Handbook, [REDACTED] and CAP protocol, [REDACTED]

[page 2 of 4]
Specimen:	Head, body of pancreas, duodenum, stomach, bile duct.
-----------	---

Procedure:	Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy.
------------	--

TUMOR FEATURES:

Tumor site:	Pancreatic head.
Tumor size:	3.4 cm.
Histologic type:	Ductal adenocarcinoma.
Histologic grade:	G2-3, moderately to poorly differentiated.
Microscopic tumor extension:	Tumor invades ampulla of Vater and duodenal wall and peripancreatic soft tissues.

MARGINS:	R0, negative.
----------	---------------

Treatment effect:	N/A.
Lymphovascular invasion:	Not identified.
Perineural invasion:	Not identified.

PATHOLOGIC TUMOR STAGING DESCRIPTORS:

Primary tumor:	pT3.
Regional lymph node:	pN1.
Distant metastasis:	N/A.
Pathologic stage:	IIB.

[page 3 of 4]
FINAL SURGICAL PATHOLOGY REPORT

Source of Specimen:

Whipple procedure

Clinical History/Operative Dx:

Pancreas carcinoma

Intraoperative Diagnosis:

FS: Whipple procedure: Bile duct margin negative. Pancreatic margin negative.

The intraoperative interpretation(s) was/were performed and rendered at

Gross Description:

Single specimen designated as Whipple procedure. Initially received in a fresh state for frozen section analysis and Oncogenotyping studies, is a generous portion of tissue consistent with a Whipple procedure, consisting of a pancreas, distal end of the stomach, and small bowel segment. The pancreas is 2.7 cm in length, 3.2 cm superior-inferior, and 4.2 cm posterior-anterior. The common bile duct margin extends out to 0.7 cm, and 0.8 cm in diameter. The gastric tissue is 9.2 cm - greater and 9.6 cm - lesser. The small bowel segment is 29.7 cm in length with an average diameter of 2.3 cm. The gastric and small bowel serosa semi-congested light pink to purple-red. The head of the pancreas demonstrates palpable firmness. The surfaces of the pancreas are now differentially inked as follows:

Anterior - yellow,
posterior (uncinate) - black,
superior - blue,
inferior - green,
pancreatic groove - red.

The small bowel length and gastric tissue are now opened, initially revealing a markedly ulcerated tumor mass obliterating the Ampulla of Vater, and upon sectioning reveals a dense, well demarcated gray tumor mass measuring up to 3.4 x 3.3 x 2.6 cm. The ulcerated depression is to a depth of 1.8 cm. The tumor mass is positioned 3.2 cm distal to the pylorus, 23.1 cm from the distal small bowel margin of resection, and 0.4 cm from the distal pancreatic margin of resection. The common bile duct lumen is probed to reveal patency with the likely accessory duct lumen (0.2 cm diameter), 0.7 cm distal to the ulcerated mass. Careful sectioning along the pancreatic duct does not reveal communication with this "accessory duct" or the common bile duct length. The tumor mass grossly abuts the inferior pancreatic margin and grossly within 0.3 cm of the mesenteric/pancreatic groove margin, 0.4 cm of the posterior uncinate margin, and grossly within 0.7 cm of the anterior surface.

The superior and superior-posterior pancreatic parenchyma demonstrates a distinct glandular, tan appearance, free of tumor involvement. A 0.8 x 0.5 cm multiloculated cyst is 0.3 cm adjacent to the common bile duct and abuts the superior pancreatic margin. A representative portion of the tumor and para-normal pancreatic tissue is submitted for Oncogenotyping studies. The distal pancreatic margin is

[page 4 of 4]
FINAL SURGICAL PATHOLOGY REPORT

shaved and submitted for frozen section analysis, with the residual frozen tissue submitted en face for permanent sections. The common bile duct surgical margin is trimmed and submitted for frozen section, with the residual frozen tissue submitted for permanent sections.

Initial examination of the peripancreatic fat reveals nineteen lymph node candidates ranging from 0.2 cm - 2.2 cm in greatest dimension. The remainder of the small bowel mucosa demonstrates partially flattened to prominent, semi-congested tan to deep red mucosal folds, with ischemic changes throughout the distal 12.3 cm length. The gastric tissue is partially flattened to wrinkled, mildly congested pink and tan. Examination of the perigastric fat reveals four lymph node candidates, 0.3 - 1.0 cm. Representative sections are submitted for microscopic evaluation.

Cassette summary:

- A1) common bile duct margin, frozen section,
- A2) distal pancreatic margin of resection, frozen section,
- A3-A4) ulcerated tumor mass/obliterated ampulla of Vater,
- A5) accessory duct and CBD relationship,
- A6) perpendicular representation of pancreas and likely approach of tumor, inferior margin,
- A7-A8) inferior pancreas, tumor,
- A9-A10) pancreatic notch margin, tumor,
- A11) anterior pancreas, contiguous sections x2,
- A12) anterior pancreas,
- A13-A15) posterior / uncinate pancreas, four pieces,
- A16) pancreas, superior, cystic lesion, length of CBD represented,
- A17) three peripancreatic lymph nodes candidates,
- A18) five peripancreatic lymph node candidates,
- A19) two peripancreatic lymph nodes candidates bisected, one along posterior periphery (black),
- A20) one peripancreatic lymph node candidates, bisected,
- A21) two peripancreatic lymph node candidates, bisected, one marked green, the other two pieces attached,
- A22) two lymph node candidates,
- A23) fatty area suspicious for lymph node content,
- A24) single lymph node bisected,
- A25) single lymph node trisected,
- A26) large flat lymph node bisected,
- A27) five perigastric lymph node candidates,
- A28) proximal gastric margin of resection represented,
- A29) distal small bowel margin resection,
- A30) representation of gastric and small bowel length. [REDACTED]

Microscopic Description:

Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered. Immunohistochemistry was performed with adequate control for OSCAR keratin.

Source: NCI Genomic Data Commons file 241dea20-96be-4f0d-9b41-89663574dfe0 (TCGA-HZ-8637.C0616007-805D-4F37-8BDD-DA6DBE188FBE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).